Somatic mutation profile of tumor specimen TCGA-KV-A6GD-01A (aliquot TCGA-KV-A6GD-01A-11D-A31X-10) from TCGA case TCGA-KV-A6GD, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 85.5 years (31,217 days).
Specimen TCGA-KV-A6GD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0f702b1-5725-40f0-ba4d-ad90a3f7ee73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KV-A6GD-10A (Blood Derived Normal), aliquot TCGA-KV-A6GD-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e04d5df-ae2e-4eeb-88d3-d6e2c1acfdb3

The open-access MAF lists 60 somatic variants for this specimen: 44 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 15, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD35 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as rs201815402, COSV62909548, COSV62911775, COSV99053003; called by muse, mutect2, varscan2
- ASPM | c.6091T>C p.Y2031H | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54140241; called by muse, mutect2, varscan2
- C2CD3 | c.3764G>C p.C1255S | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.703); catalogued as COSV58102513; called by muse, mutect2, varscan2
- COL4A2 | c.1937T>A p.F646Y | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0.017); catalogued as COSV64635358; called by muse, mutect2, varscan2
- COL4A3 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67421235; called by muse, mutect2, varscan2
- CREBRF | c.1064A>T p.E355V | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV51636916; called by muse, mutect2, varscan2
- CTSL | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58247808; called by muse, mutect2, varscan2
- CTTNBP2NL | c.961A>G p.R321G | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV54747515; called by muse, mutect2, varscan2
- DOT1L | c.3674C>T p.A1225V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs762727256, COSV67113919; called by muse, mutect2, varscan2
- EEF1B2 | c.463A>T p.M155L | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV51914288; called by muse, mutect2, varscan2
- EIF2AK1 | c.718A>C p.I240L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV52243879; called by muse, mutect2, varscan2
- FAN1 | c.972T>G p.H324Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV62952388; called by muse, mutect2, varscan2
- FRMD8 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs1333440318, COSV58214534; called by muse, mutect2, varscan2
- GRIN2A | c.2912A>G p.Q971R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV58059011; called by muse, mutect2, varscan2
- GTF2A1 | c.691A>T p.N231Y | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV53338758; called by muse, mutect2, varscan2
- HIVEP2 | c.5138C>A p.P1713H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV50080373; called by muse, mutect2, varscan2
- IFIT5 | c.56A>G p.H19R | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65655995; called by muse, mutect2, varscan2
- IFT172 | c.989A>T p.Y330F | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.2); catalogued as COSV53140486; called by muse, mutect2, varscan2
- ILDR2 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV54836051; called by muse, mutect2, varscan2
- ISL1 | c.64A>G p.N22D | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.216); catalogued as COSV57936020; called by muse, mutect2, varscan2
- ITGAX | c.1087-1G>A p.X363_splice | Splice Site (SNP) | VAF 9/71 reads (13%) | catalogued as rs759649296, COSV51652407; called by muse, mutect2, varscan2
- MON2 | c.3716T>A p.L1239Q | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54816346; called by muse, mutect2, varscan2
- MRPS31 | c.844T>A p.F282I | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV60269153; called by muse, mutect2
- MUS81 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.13); catalogued as COSV57261704; called by muse, mutect2, varscan2
- NETO1 | c.791T>A p.L264H | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100198443; called by muse, mutect2
- PSG5 | c.964+1G>A p.X322_splice | Splice Site (SNP) | VAF 12/112 reads (11%) | catalogued as rs1274743612, COSV61655569; called by muse, mutect2, varscan2
- RASGRF1 | c.479T>A p.L160H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV69183859; called by muse, mutect2, varscan2
- RNF103 | c.839T>C p.I280T | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1397912638, COSV52897252; called by muse, mutect2
- RP2 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV54463575; called by muse, mutect2, varscan2
- RYR1 | c.2082C>G p.Y694* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV62112911; called by muse, mutect2, varscan2
- SEC24A | c.3174G>C p.E1058D | Missense Mutation (SNP) | VAF 42/386 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV67306426; called by muse, mutect2, varscan2
- SIN3A | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 11/82 reads (13%) | catalogued as COSV64582805, COSV64585383; called by muse, mutect2, varscan2
- SLC20A1 | c.1697T>C p.L566P | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1360222173, COSV55613377; called by muse, mutect2, varscan2
- SLC4A4 | c.2645T>C p.L882P (on ENST00000264485 / NM_001098484.3; = p.L838P on NM_003759.4) | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as COSV52640672; called by muse, varscan2
- SRSF1 | c.246C>A p.Y82* | Nonsense Mutation (SNP) | VAF 19/185 reads (10%) | catalogued as COSV51966126, COSV51966726; called by muse, mutect2, varscan2
- SYVN1 | c.379del p.M127Wfs*38 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as COSV53696647; called by mutect2, pindel, varscan2
- TCIRG1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372690969; called by muse, mutect2, varscan2
- TMEM115 | c.277T>C p.W93R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51705697; called by muse, mutect2, varscan2
- UBR5 | c.6608A>G p.D2203G | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV55302092; called by muse, mutect2
- USH1C | c.1156T>G p.L386V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV50039909; called by muse, mutect2, varscan2
- YAP1 | c.1399G>T p.G467* (on ENST00000282441 / NM_001130145.3; = p.G413* on NM_006106.5) | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as COSV56780209; called by muse, mutect2, varscan2
- ANKRD44 | c.1915del p.H639Mfs*4 | Frame Shift Del (DEL) | VAF 25/128 reads (20%) | called by mutect2, pindel, varscan2
- SESN1 | c.1315del p.T439Lfs*34 (on ENST00000356644 / NM_001199933.1; = p.T498Lfs*34 on NM_014454.3) | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- TRPM3 | c.4869dup p.E1624Rfs*39 (on ENST00000357533 / NM_001366142.2; = p.E1479Rfs*39 on NM_020952.6) | Frame Shift Ins (INS) | VAF 14/125 reads (11%) | called by mutect2, pindel, varscan2
- ACTR5 | c.801T>C p.D267= | Silent (SNP) | VAF 53/239 reads (22%) | catalogued as COSV54762400; called by muse, mutect2, varscan2
- ARHGAP32 | c.825T>C p.P275= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as rs1565403757, COSV59856696; called by muse, mutect2, varscan2
- CLCN1 | c.2958G>A p.L986= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV58373081; called by muse, mutect2, varscan2
- CLSTN3 | c.2154T>C p.D718= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV56940967; called by muse, mutect2, varscan2
- FHL3 | c.681C>A p.P227= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV65952926; called by muse, mutect2
- INPPL1 | c.3315A>G p.P1105= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV53359927; called by muse, mutect2, varscan2
- MALL | c.84C>T p.F28= | Silent (SNP) | VAF 20/165 reads (12%) | catalogued as COSV55601538; called by muse, mutect2, varscan2
- NLRP8 | c.2850C>T p.N950= | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as COSV52594967; called by muse, mutect2, varscan2
- PREX1 | c.318C>T p.I106= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs763889894, COSV64257549; called by muse, mutect2, varscan2
- RAB17 | c.57G>T p.V19= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV52817180; called by muse, mutect2, varscan2
- SETD3 | c.138G>A p.E46= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV59287613; called by muse, mutect2, varscan2
- SLC6A6 | c.816A>G p.A272= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs773865951, COSV62653333; called by muse, mutect2, varscan2
- TCF7L1 | c.261C>G p.R87= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as rs1340338349, COSV56404076; called by muse, mutect2, varscan2
- TMEM236 | c.1005T>C p.N335= | Silent (SNP) | VAF 9/158 reads (6%) | called by muse, mutect2
- TRIM62 | c.735G>A p.L245= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV52223982; called by muse, mutect2
- FGFR3 | c.*878T>A | 3'UTR (SNP) | VAF 16/51 reads (31%) | catalogued as COSV53423079; called by muse, mutect2, varscan2
